Somatic mutation profile of tumor specimen TCGA-P3-A6T4-01A (aliquot TCGA-P3-A6T4-01A-11D-A34J-08) from TCGA case TCGA-P3-A6T4, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 54.8 years (20,027 days).
Specimen TCGA-P3-A6T4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcfc2ddb-a841-44bf-806f-bc7aa691daa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A6T4-10A (Blood Derived Normal), aliquot TCGA-P3-A6T4-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67889816-6feb-4632-b375-8017114fb8c7

The open-access MAF lists 153 somatic variants for this specimen: 109 protein-altering or splice-affecting, 40 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 40, Nonsense Mutation 12, Frame Shift Del 4, Splice Site 2, Intron 2, 5'UTR 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 25/100 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.615T>A p.Y205* | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | hotspot (GDC flag); catalogued as rs786202222, COSV52713698, COSV52808763, COSV52840738; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 28/452 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV99257468; called by muse, mutect2
- ADGRF5 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.296); catalogued as rs745320744, COSV99346328; called by muse, mutect2, varscan2
- ALPG | c.31G>C p.G11R | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as rs543783627, COSV99779460; called by muse, varscan2
- APOA4 | c.620A>G p.E207G | Missense Mutation (SNP) | VAF 119/288 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as COSV63360576; called by muse, mutect2, varscan2
- APOB | c.7363C>T p.Q2455* | Nonsense Mutation (SNP) | VAF 53/309 reads (17%) | catalogued as COSV99267528; called by muse, mutect2, varscan2
- AR | c.37C>G p.R13G | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101019301, COSV65961534; called by muse, mutect2, varscan2
- ASTN2 | c.1163C>G p.S388C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.219); catalogued as COSV100530066; called by muse, mutect2, varscan2
- ATP13A4 | c.2984G>C p.R995T | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV100710683; called by muse, mutect2, varscan2
- BLVRA | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99646100; called by muse, mutect2, varscan2
- CACNA1G | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV100662429; called by muse, mutect2, varscan2
- CCDC14 | c.1404G>C p.Q468H (on ENST00000488653; = p.Q420H on NM_022757.5) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100113417, COSV59943214, COSV59946420; called by muse, mutect2
- CCDC50 | c.1138-2A>C p.X380_splice (on ENST00000392455 / NM_178335.3; = p.X204_splice on NM_174908.4) | Splice Site (SNP) | VAF 13/102 reads (13%) | catalogued as COSV101165352, COSV66668750; called by muse, mutect2, varscan2
- CCN3 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV99423318; called by muse, mutect2
- CDH6 | c.2317C>T p.R773* | Nonsense Mutation (SNP) | VAF 58/182 reads (32%) | catalogued as rs867047355, COSV99420626; called by muse, mutect2, varscan2
- CDK17 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99703015; called by muse, mutect2
- CHD8 | c.3940G>C p.A1314P (on ENST00000646647 / NM_001170629.2; = p.A1035P on NM_020920.4) | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100783861; called by muse, mutect2, varscan2
- CTDSPL2 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99527193; called by muse, mutect2, varscan2
- DCAF12 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs1254161878, COSV100778403; called by muse, mutect2, varscan2
- DENND4B | c.2673G>C p.L891F | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100768864; called by muse, mutect2
- DOCK11 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 146/206 reads (71%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV99354594; called by muse, mutect2, varscan2
- EIF1AD | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 78/278 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.066); catalogued as COSV100381415; called by muse, mutect2, varscan2
- EP300 | c.4355C>T p.P1452L | Missense Mutation (SNP) | VAF 87/169 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV54326768, COSV54346531; called by muse, mutect2, varscan2
- ESX1 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 102/136 reads (75%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV101006497; called by muse, mutect2, varscan2
- ETNK1 | c.817G>C p.D273H | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.738); catalogued as COSV99860947; called by muse, mutect2
- FAM241A | c.167C>G p.S56* | Nonsense Mutation (SNP) | VAF 58/171 reads (34%) | catalogued as COSV100551294; called by muse, mutect2, varscan2
- FANCA | c.4051G>A p.E1351K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as rs761934804, COSV57066822, COSV99235300; called by muse, mutect2, varscan2
- FAR2 | c.1324A>T p.K442* | Nonsense Mutation (SNP) | VAF 39/121 reads (32%) | catalogued as COSV99479542; called by muse, mutect2, varscan2
- FBXO8 | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.258); catalogued as COSV101183726; called by muse, mutect2, varscan2
- FCHO1 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as rs747467663, COSV99406403; called by muse, mutect2, varscan2
- FLG | c.5314C>G p.H1772D | Missense Mutation (SNP) | VAF 67/526 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV100912036; called by muse, mutect2, varscan2
- FREM1 | c.4552G>A p.A1518T | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV101085290; called by muse, mutect2, varscan2
- GABRE | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100944360; called by muse, mutect2, varscan2
- GABRE | c.1281G>C p.Q427H | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.601); catalogued as COSV100944361; called by muse, mutect2, varscan2
- GPR101 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs766985500, COSV99981445; called by muse, mutect2, varscan2
- IFI16 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV99858100; called by muse, mutect2
- IGKV3-20 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs548180684; called by muse, mutect2, varscan2
- IL4R | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV99405357; called by muse, mutect2, varscan2
- JAG1 | c.1251G>C p.E417D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as COSV99653472; called by muse, mutect2, varscan2
- KCNQ4 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100714404; called by muse, mutect2, varscan2
- KCNT2 | c.2708A>T p.K903M | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54071916, COSV99656332; called by muse, mutect2, varscan2
- KCNT2 | c.1254G>C p.Q418H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as COSV99656335; called by muse, mutect2, varscan2
- KMT2A | c.4742A>G p.Y1581C | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as rs1565293702, COSV100629471; called by muse, mutect2, varscan2
- LUC7L2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99693381; called by muse, mutect2, varscan2
- LY96 | c.476C>G p.S159* | Nonsense Mutation (SNP) | VAF 18/132 reads (14%) | catalogued as COSV99514681; called by muse, mutect2, varscan2
- MARK4 | c.359A>T p.K120M | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99488735; called by muse, mutect2, varscan2
- MFNG | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100812936; called by muse, mutect2, varscan2
- MGAT5 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs770888873, COSV99925005; called by muse, mutect2, varscan2
- MICALL2 | c.2672C>A p.S891Y | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99876232; called by muse, mutect2, varscan2
- MTERF3 | c.51G>C p.L17F | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.172); catalogued as COSV99750033; called by muse, mutect2, varscan2
- NCOA6 | c.4988C>A p.S1663* | Nonsense Mutation (SNP) | VAF 37/104 reads (36%) | catalogued as COSV100750288; called by muse, mutect2, varscan2
- NLGN1 | c.2007A>C p.Q669H | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.605); catalogued as COSV100850042, COSV64332379; called by muse, mutect2
- NR4A1 | c.1469C>G p.S490* | Nonsense Mutation (SNP) | VAF 26/92 reads (28%) | catalogued as COSV99671647; called by muse, mutect2, varscan2
- OR11A1 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV101010733; called by muse, mutect2, varscan2
- PGAP1 | c.2386G>C p.D796H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV100698343; called by muse, mutect2, varscan2
- PNISR | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100984423; called by muse, mutect2, varscan2
- PPM1D | c.1119C>G p.I373M | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100011120; called by muse, mutect2, varscan2
- PPM1D | c.1307dup p.P437Tfs*6 | Frame Shift Ins (INS) | VAF 112/264 reads (42%) | catalogued as rs1188388037; called by mutect2, pindel, varscan2
- PRRC2A | c.883A>T p.M295L | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV100784626; called by muse, mutect2, varscan2
- PTGFRN | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV101277449; called by muse, mutect2, varscan2
- PTPRR | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99032188; called by muse, mutect2, varscan2
- PTPRZ1 | c.671C>G p.S224* | Nonsense Mutation (SNP) | VAF 20/198 reads (10%) | catalogued as COSV101100738; called by muse, mutect2, varscan2
- PWWP3B | c.1442G>C p.G481A | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.998); catalogued as COSV100531570; called by muse, mutect2, varscan2
- RASGEF1C | c.1304G>A p.G435D | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100746309; called by muse, mutect2, varscan2
- RASIP1 | c.2185G>C p.E729Q | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.063); catalogued as COSV55803467, COSV99710428, COSV99711072; called by muse, mutect2, varscan2
- RBM48 | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1384637817, COSV50396986; called by muse, mutect2, varscan2
- RFX3 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV100175730; called by muse, mutect2, varscan2
- RNF8 | c.1074G>C p.K358N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100009860; called by muse, mutect2
- RPH3AL | c.126G>T p.R42S | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100047792; called by muse, mutect2
- S100A12 | c.55T>A p.S19T | Missense Mutation (SNP) | VAF 85/250 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100907181; called by muse, mutect2, varscan2
- SASH3 | c.842T>G p.L281R | Missense Mutation (SNP) | VAF 59/92 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100795290; called by muse, mutect2, varscan2
- SCARA3 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs146536900; called by muse, mutect2
- SGF29 | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV100187339; called by muse, mutect2, varscan2
- SKP2 | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.045); catalogued as COSV99948271; called by muse, mutect2, varscan2
- SLC25A14 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 19/297 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV99502592; called by muse, mutect2
- SLC5A11 | c.829G>C p.G277R | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100762892, COSV61741940; called by muse, mutect2, varscan2
- SNCB | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV100031362; called by muse, mutect2, varscan2
- SPEM2 | c.1351A>T p.N451Y | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100424469; called by muse, mutect2, varscan2
- SPINK2 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); catalogued as COSV99954286; called by muse, mutect2, varscan2
- ST18 | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV99390860; called by muse, varscan2
- SULT1E1 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 28/69 reads (41%) | catalogued as COSV99895201; called by muse, mutect2, varscan2
- SYCN | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs374430683; called by muse, mutect2
- TAAR1 | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99257718; called by muse, mutect2
- TAB1 | c.345G>C p.R115S | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV53370279, COSV99336256; called by muse, mutect2, varscan2
- TLR4 | c.729G>T p.M243I (on ENST00000355622 / NM_138554.5; = p.M203I on NM_003266.4) | Missense Mutation (SNP) | VAF 77/134 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV100790688, COSV62922621; called by muse, mutect2, varscan2
- TSPAN31 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as COSV99224125; called by muse, mutect2, varscan2
- TTBK2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 58/292 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99142341; called by muse, mutect2, varscan2
- UBN1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.395); catalogued as COSV99278539; called by muse, mutect2, varscan2
- USH2A | c.11857A>T p.S3953C | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100241413, COSV56325656; called by muse, mutect2, varscan2
- VIRMA | c.4364A>T p.E1455V | Missense Mutation (SNP) | VAF 98/169 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.087); catalogued as COSV99889301; called by muse, mutect2, varscan2
- VPS13C | c.10039G>A p.E3347K (on ENST00000644861 / NM_020821.3; = p.E3304K on NM_017684.5) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs559514846, COSV99829926; called by muse, mutect2, varscan2
- WFDC10B | c.79A>T p.M27L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100225232; called by muse, mutect2, varscan2
- XPO7 | c.1373G>C p.C458S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV99381970; called by muse, mutect2, varscan2
- YAF2 | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100586436; called by muse, mutect2, varscan2
- ZC3H6 | c.1683G>A p.M561I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV100674807; called by muse, mutect2, varscan2
- ZIK1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56736549, COSV56737075; called by muse, mutect2, varscan2
- ZMYM1 | c.96+2T>G p.X32_splice | Splice Site (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100721045; called by muse, mutect2, varscan2
- ZNF189 | c.1706A>C p.K569T | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV99407298; called by muse, mutect2, varscan2
- ZNF207 | c.222C>G p.D74E | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100340674; called by muse, mutect2
- ZNF512 | c.1372C>T p.H458Y | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100820775; called by muse, mutect2, varscan2
- ZNF540 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs1290362936, COSV100329871; called by muse, mutect2, varscan2
- ZNF808 | c.248A>G p.E83G | Missense Mutation (SNP) | VAF 79/460 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100708162; called by muse, mutect2, varscan2
- ZNF835 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1225882932, COSV73379484; called by muse, mutect2, varscan2
- KMT2D | c.6653del p.P2218Lfs*46 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- MTHFD1L | c.1073_1074del p.P358Rfs*4 | Frame Shift Del (DEL) | VAF 13/105 reads (12%) | called by mutect2, pindel, varscan2
- NEBL | c.187_192del p.D63_K64del | In Frame Del (DEL) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
- SLC35G2 | c.779del p.M260Rfs*3 | Frame Shift Del (DEL) | VAF 195/713 reads (27%) | called by mutect2, pindel, varscan2
- ZNF526 | c.383del p.D128Vfs*41 | Frame Shift Del (DEL) | VAF 33/148 reads (22%) | called by mutect2, pindel, varscan2
- AQP12A | c.234C>A p.A78= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100538961; called by muse, mutect2, varscan2
- BTNL8 | c.480C>T p.F160= | Silent (SNP) | VAF 172/542 reads (32%) | catalogued as rs762739488, COSV99180570; called by muse, mutect2, varscan2
- CENPN | c.405T>C p.I135= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV100001579; called by muse, mutect2
- CLCF1 | c.519T>A p.P173= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100425694; called by muse, mutect2, varscan2
- CRYBG2 | c.483C>T p.L161= | Silent (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- FLG | c.4917T>C p.D1639= | Silent (SNP) | VAF 182/577 reads (32%) | catalogued as rs752654274, COSV64237729; called by muse, mutect2, varscan2
- FLG2 | c.1977A>T p.G659= | Silent (SNP) | VAF 49/685 reads (7%) | catalogued as COSV101166148; called by muse, mutect2
- GFRA1 | c.252C>G p.L84= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV62604146, COSV62607031; called by muse, mutect2, varscan2
- GRIK5 | c.2196C>G p.L732= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV53480205, COSV99491278; called by muse, mutect2, varscan2
- GZF1 | c.1071C>T p.F357= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as rs775077224, COSV100582658; called by muse, mutect2, varscan2
- HSD17B6 | c.270C>T p.I90= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs368361992; called by muse, mutect2, varscan2
- INSR | c.3810C>A p.R1270= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV100253269; called by muse, mutect2, varscan2
- ITIH4 | c.936C>G p.L312= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as rs917693; called by muse, mutect2, varscan2
- IYD | c.291C>G p.L97= | Silent (SNP) | VAF 10/133 reads (8%) | catalogued as COSV99990013; called by muse, mutect2
- NDUFB4 | c.294C>A p.L98= | Silent (SNP) | VAF 153/525 reads (29%) | catalogued as COSV51742985, COSV99481938; called by muse, mutect2, varscan2
- NEB | c.12924C>G p.V4308= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV99427171; called by muse, mutect2, varscan2
- NKD1 | c.444C>T p.N148= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs759333024, COSV99194110; called by muse, mutect2, varscan2
- OR5K3 | c.240G>A p.K80= | Silent (SNP) | VAF 70/574 reads (12%) | catalogued as COSV101051677; called by muse, mutect2, varscan2
- PCDHGA2 | c.255C>T p.V85= | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as COSV99545613; called by muse, mutect2, varscan2
- PIGQ | c.1470C>T p.L490= | Silent (SNP) | VAF 81/299 reads (27%) | catalogued as rs1253169688, COSV99216463; called by muse, mutect2, varscan2
- PRAMEF12 | c.1209G>A p.L403= | Silent (SNP) | VAF 46/230 reads (20%) | catalogued as COSV100743571; called by muse, mutect2, varscan2
- PRUNE2 | c.3981G>A p.E1327= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV100945061; called by muse, mutect2, varscan2
- PSEN2 | c.1029C>G p.P343= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV100423263; called by muse, mutect2, varscan2
- RBM34 | c.1218A>G p.K406= | Silent (SNP) | VAF 35/173 reads (20%) | catalogued as rs1274080104, COSV64013673; called by muse, mutect2, varscan2
- RELT | c.267C>G p.L89= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV99293072; called by muse, mutect2, varscan2
- RPRD2 | c.1299G>A p.V433= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs1357197513, COSV100955328; called by muse, mutect2, varscan2
- RPS26 | c.174C>G p.V58= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV100009315; called by muse, mutect2, varscan2
- SCN4A | c.5166C>G p.L1722= | Silent (SNP) | VAF 22/167 reads (13%) | catalogued as COSV101438630; called by muse, mutect2, varscan2
- SEC23B | c.750G>A p.Q250= | Silent (SNP) | VAF 11/181 reads (6%) | catalogued as rs959790425, COSV99358047; called by muse, mutect2
- SETD4 | c.147C>T p.N49= | Silent (SNP) | VAF 38/181 reads (21%) | catalogued as COSV100145736; called by muse, mutect2, varscan2
- SPEM2 | c.1350G>T p.R450= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV100424468, COSV61603148; called by muse, mutect2, varscan2
- TLR5 | c.1707A>G p.V569= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as rs572228250, COSV100643372; called by muse, mutect2, varscan2
- TMCO6 | c.879T>C p.A293= | Silent (SNP) | VAF 86/191 reads (45%) | catalogued as COSV99347365; called by muse, mutect2, varscan2
- TRPV1 | c.1581G>A p.V527= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV99440535; called by muse, mutect2, varscan2
- TXK | c.1149G>A p.R383= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as COSV99972783; called by muse, mutect2, varscan2
- TYK2 | c.3540C>T p.A1180= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV99315305; called by muse, mutect2, varscan2
- WASHC2A | c.3249C>G p.L1083= | Silent (SNP) | VAF 10/226 reads (4%) | catalogued as rs1483981823; called by muse, mutect2
- WDR12 | c.912C>T p.S304= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs762601516, COSV99651217; called by muse, mutect2, varscan2
- ZNF439 | c.1499A>G p.*500= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV100397548; called by muse, mutect2, varscan2
- ZNF607 | c.1266A>G p.K422= | Silent (SNP) | VAF 73/240 reads (30%) | catalogued as COSV100777946; called by muse, mutect2, varscan2
- GRM1 | c.-2C>G | 5'UTR (SNP) | VAF 57/218 reads (26%) | catalogued as COSV99268594; called by muse, mutect2, varscan2
- HIF3A | c.878-104C>T | Intron (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- LYZL2 | c.-1G>T | 5'UTR (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100940641, COSV64685238; called by muse, mutect2, varscan2
- RBM44 | c.-98-1719G>A | Intron (SNP) | VAF 9/70 reads (13%) | catalogued as rs1214433811, COSV100390098; called by muse, mutect2, varscan2
